Somatic mutation profile of tumor specimen TCGA-BC-4073-01B (aliquot TCGA-BC-4073-01B-02D-A12Z-10) from TCGA case TCGA-BC-4073, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 73.4 years (26,795 days).
Specimen TCGA-BC-4073-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea1e05bf-9d27-41ad-a569-9639193bcf8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-4073-10A (Blood Derived Normal), aliquot TCGA-BC-4073-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ed9f5b9-22cd-4a03-807b-9a1eeb26adaf

The open-access MAF lists 159 somatic variants for this specimen: 111 protein-altering or splice-affecting, 41 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 41, Nonsense Mutation 8, RNA 4, In Frame Del 2, Frame Shift Del 2, Intron 2, Splice Site 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADAC | c.933T>G p.Y311* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as COSV51760918, COSV51761472; called by muse, mutect2, varscan2
- ABCC8 | c.2713G>T p.G905C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV56857790; called by muse, mutect2
- ACVR1B | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57780281; called by muse, mutect2, varscan2
- ADGRA2 | c.1965C>G p.H655Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV59443374, COSV59447268; called by muse, varscan2
- AKAP1 | c.1813G>T p.V605F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV58472966; called by muse, mutect2, varscan2
- AKAP4 | c.2451T>A p.S817R | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV62075475; called by muse, mutect2, varscan2
- AKAP6 | c.6073A>G p.N2025D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV55233473; called by muse, mutect2, varscan2
- ALAS1 | c.978G>A p.M326I | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV59629658; called by muse, varscan2
- ALB | c.50A>G p.Y17C | Missense Mutation (SNP) | VAF 58/323 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.706); catalogued as COSV55742576; called by muse, mutect2, varscan2
- ALDH3A1 | c.614C>G p.T205S | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56736899; called by muse, mutect2, varscan2
- ASIC4 | c.377C>A p.S126* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as COSV61733521; called by muse, mutect2, varscan2
- BNC2 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV66157255; called by muse, mutect2, varscan2
- CACNG4 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as COSV50925055, COSV50927984; called by muse, mutect2, varscan2
- CDC14B | c.1146G>C p.E382D | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV55794028; called by muse, mutect2, varscan2
- CDH11 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV51777438; called by muse, varscan2
- CELSR1 | c.4535C>T p.T1512M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs573686247, COSV53099821; called by muse, mutect2, varscan2
- CHRNA9 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59576265; called by muse, mutect2, varscan2
- CLCA2 | c.2092A>T p.S698C | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV100991477, COSV65288750; called by muse, mutect2, varscan2
- COA8 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 133/528 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV56029713; called by muse, mutect2, varscan2
- CRY1 | c.1715A>C p.D572A | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV50491692; called by muse, varscan2
- DGKG | c.896G>A p.G299D | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53972783; called by muse, mutect2, varscan2
- ELAVL1 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60968974; called by muse, mutect2, varscan2
- EPHB1 | c.2182A>T p.I728F | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67671541; called by muse, mutect2, varscan2
- FAM98A | c.1303A>G p.S435G | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV53211908; called by muse, mutect2, varscan2
- FBF1 | c.1013C>G p.P338R (on ENST00000586717; = p.P352R on NM_001319193.1) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as COSV59867040; called by muse, mutect2
- FBN2 | c.1553G>C p.R518P | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52545016; called by muse, mutect2, varscan2
- FOXS1 | c.425G>C p.G142A | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.43); catalogued as rs756957353, COSV54068346; called by muse, mutect2, varscan2
- FPR3 | c.450G>C p.W150C | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59330931, COSV59332141; called by muse, mutect2
- GKAP1 | c.431A>G p.H144R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs745913937, COSV64489812; called by muse, mutect2
- GLYAT | c.702G>C p.L234F | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as COSV53540347, COSV53540672; called by muse, mutect2, varscan2
- GRIK4 | c.1957A>T p.I653F | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV70807211; called by muse, mutect2, varscan2
- GRM6 | c.1610G>A p.C537Y | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99179965; called by muse, mutect2
- GTF3C2 | c.1996C>G p.P666A | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.159); catalogued as rs1248429123, COSV53128291, COSV53128773; called by muse, mutect2, varscan2
- GTPBP4 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs144664436, COSV100672947; called by muse, varscan2
- H3C2 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV52518963, COSV99451494; called by muse, mutect2, varscan2
- HCCS | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58239710; called by muse, mutect2, varscan2
- IGSF3 | c.421+2T>A p.X141_splice | Splice Site (SNP) | VAF 68/293 reads (23%) | catalogued as COSV59598602; called by muse, mutect2, varscan2
- IMPG1 | c.1001A>T p.E334V | Missense Mutation (SNP) | VAF 71/330 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV64061893; called by muse, mutect2, varscan2
- INPPL1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV53359359; called by muse, mutect2, varscan2
- IQGAP1 | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as rs959006091, COSV51591356; called by muse, mutect2, varscan2
- ITSN1 | c.2239G>A p.A747T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66084361, COSV66086040; called by muse, mutect2, varscan2
- JKAMP | c.522T>G p.Y174* (on ENST00000554271 / NM_001284201.1; = p.Y160* on NM_016475.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | catalogued as COSV54201493; called by mutect2, varscan2
- JMJD1C | c.4228A>G p.S1410G | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as rs1397956442, COSV100550854; called by muse, mutect2, varscan2
- KCNJ4 | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV57858777; called by muse, mutect2, varscan2
- KDM3B | c.4162G>T p.G1388W | Missense Mutation (SNP) | VAF 66/237 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58688069; called by muse, mutect2, varscan2
- KDM3B | c.4163G>T p.G1388V | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100070261; called by muse, mutect2, varscan2
- KIF21B | c.909G>T p.L303F | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59766663; called by muse, mutect2, varscan2
- KLF6 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 47/162 reads (29%) | catalogued as COSV51496233; called by muse, mutect2, varscan2
- LGALS9B | c.830C>G p.A277G (on ENST00000423676 / NM_001367292.1; = p.A276G on NM_001042685.2) | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.684); catalogued as COSV60865909; called by muse, mutect2, varscan2
- LRRIQ1 | c.1853C>T p.S618L | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67825551; called by muse, mutect2, varscan2
- LY75 | c.4731T>A p.D1577E | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.574); catalogued as COSV55108097, COSV55113083; called by muse, mutect2, varscan2
- MBD1 | c.1324G>T p.E442* (on ENST00000269468 / NM_001323950.1; = p.E386* on NM_002384.2) | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as COSV54006950; called by muse, mutect2, varscan2
- NFATC2 | c.1474A>C p.I492L | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.465); catalogued as COSV65361030; called by muse, mutect2, varscan2
- NLRP3 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV60219978, COSV60230909; called by muse, mutect2, varscan2
- NOS1AP | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.511); catalogued as CM104094, COSV62640166; called by muse, mutect2, varscan2
- NRDE2 | c.1663C>A p.P555T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs752962579, COSV62964766; called by muse, mutect2, varscan2
- OR51G1 | c.728G>T p.C243F | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58970993; called by muse, mutect2, varscan2
- OSGEPL1 | c.1037G>A p.C346Y | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV51463954; called by muse, mutect2, varscan2
- P2RY1 | c.307A>C p.T103P | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV59310447; called by muse, mutect2, varscan2
- PADI2 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV64946702; called by muse, mutect2, varscan2
- PCDH9 | c.3610C>T p.H1204Y (on ENST00000377865 / NM_203487.3; = p.H1170Y on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as rs760160903, COSV60590330; called by muse, mutect2, varscan2
- PCDH9 | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as COSV60590337; called by muse, mutect2, varscan2
- PCDHA2 | c.2285A>T p.E762V | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.206); catalogued as COSV65371127; called by muse, mutect2, varscan2
- PDZD2 | c.956A>T p.Q319L | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV56872596; called by muse, mutect2, varscan2
- PDZRN3 | c.1103T>C p.M368T | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV55215379; called by muse, mutect2, varscan2
- PFKP | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776455980, COSV66901592; called by muse, mutect2, varscan2
- PJVK | c.764G>C p.R255T | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.066); catalogued as COSV64307240, COSV64307407; called by muse, mutect2, varscan2
- PMS1 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as COSV59720089; called by muse, mutect2, varscan2
- PPP2R5B | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51213221; called by muse, mutect2, varscan2
- PTCHD3 | c.1049T>C p.F350S | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as COSV71257273; called by muse, mutect2, varscan2
- PXMP4 | c.349G>T p.G117* | Nonsense Mutation (SNP) | VAF 35/145 reads (24%) | catalogued as COSV54134556; called by muse, mutect2, varscan2
- RAD9B | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as rs1456277934, COSV63777715; called by muse, mutect2, varscan2
- RBM46 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55982002; called by muse, mutect2, varscan2
- RCC2 | c.1102A>G p.K368E | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV100965206; called by muse, mutect2, varscan2
- RELL2 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV51838687, COSV99781232; called by muse, mutect2, varscan2
- RYR2 | c.11357A>C p.D3786A | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV63713515; called by muse, mutect2, varscan2
- SACM1L | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1181029098, COSV66615209; called by muse, mutect2, varscan2
- SELENOO | c.1629T>G p.S543R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV50584688; called by muse, mutect2, varscan2
- SFMBT2 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as rs1214550778, COSV62816660; called by muse, mutect2, varscan2
- SLC17A1 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV55078834, COSV55082287; called by muse, mutect2, varscan2
- SLC36A1 | c.215T>A p.V72E | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV54656377; called by muse, mutect2, varscan2
- SLC39A8 | c.493T>G p.F165V | Missense Mutation (SNP) | VAF 77/281 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63224203; called by muse, mutect2, varscan2
- SLC8A1 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60496513; called by mutect2, varscan2
- SLIT3 | c.665A>T p.H222L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV60633326; called by muse, mutect2, varscan2
- SPAM1 | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs376151172, COSV56147892; called by muse, mutect2, varscan2
- SPIDR | c.1181C>G p.S394* | Nonsense Mutation (SNP) | VAF 29/112 reads (26%) | catalogued as COSV52390712; called by muse, mutect2, varscan2
- SUV39H2 | c.218A>C p.D73A (on ENST00000354919 / NM_001193424.2; = p.D13A on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.043); catalogued as COSV57955536; called by muse, mutect2, varscan2
- TG | c.4754C>T p.A1585V | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1226127208, COSV55094057, COSV99603064; called by muse, mutect2, varscan2
- THSD7B | c.1614G>T p.E538D | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.071); catalogued as COSV99758409; called by muse, mutect2, varscan2
- THSD7B | c.1615G>T p.D539Y | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99758412; called by muse, mutect2, varscan2
- TLL1 | c.2440T>A p.L814I | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV50323551; called by muse, mutect2, varscan2
- TMEM184B | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV62672798, COSV62674289; called by muse, mutect2, varscan2
- TMPRSS11F | c.730C>A p.L244I | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.228); catalogued as COSV62469370; called by muse, mutect2, varscan2
- TRAPPC8 | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV51977371; called by muse, mutect2, varscan2
- TRPA1 | c.807G>T p.E269D | Missense Mutation (SNP) | VAF 57/224 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV51574136; called by muse, mutect2, varscan2
- TRPT1 | c.466G>T p.A156S (on ENST00000317459 / NM_001160393.1; = p.A107S on NM_031472.4) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as rs1404719597, COSV54175807; called by muse, mutect2, varscan2
- TSEN2 | c.521A>T p.N174I | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV53191031; called by muse, mutect2, varscan2
- UBE2J2 | c.521A>T p.Q174L | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV59573878; called by muse, mutect2, varscan2
- USH2A | c.11402C>T p.P3801L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.266); catalogued as rs763057404, COSV56395581, COSV56436299; called by muse, mutect2, varscan2
- VWA3A | c.2219A>G p.K740R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV55395055; called by muse, mutect2, varscan2
- WASHC4 | c.366A>T p.G122= | Splice Region (SNP) | VAF 72/363 reads (20%) | catalogued as COSV59892352; called by muse, mutect2, varscan2
- ZC3H11A | c.1272A>C p.K424N | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV59750220; called by muse, mutect2, varscan2
- ZMIZ2 | c.4A>T p.N2Y | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV54811018; called by muse, mutect2, varscan2
- ZNF28 | c.951T>A p.H317Q | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60425343; called by muse, mutect2, varscan2
- CBWD5 | c.258del p.K86Nfs*3 | Frame Shift Del (DEL) | VAF 67/534 reads (13%) | called by mutect2, varscan2
- CDC42BPA | c.1415_1417del p.L472del | In Frame Del (DEL) | VAF 100/394 reads (25%) | called by mutect2, pindel, varscan2
- DIXDC1 | c.924_926del p.L310del (on ENST00000440460 / NM_001037954.4; = p.L99del on NM_033425.4) | In Frame Del (DEL) | VAF 51/132 reads (39%) | called by mutect2, pindel, varscan2
- IGHV1-3 | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- MUC2 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- POTEA | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RNF133 | c.210_211del p.R70Sfs*17 | Frame Shift Del (DEL) | VAF 20/73 reads (27%) | called by pindel, varscan2
- AASDH | c.3135G>T p.G1045= | Silent (SNP) | VAF 50/188 reads (27%) | catalogued as COSV52710645; called by muse, mutect2, varscan2
- ABCA13 | c.7914T>A p.I2638= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV71294341; called by muse, mutect2, varscan2
- ACVR1B | c.609G>T p.V203= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as COSV57780262; called by muse, mutect2, varscan2
- CEP152 | c.3057T>C p.C1019= | Silent (SNP) | VAF 49/189 reads (26%) | catalogued as COSV57864897; called by muse, mutect2, varscan2
- COL16A1 | c.1962A>C p.P654= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as COSV54713756; called by muse, mutect2, varscan2
- EXOC1 | c.1935G>A p.R645= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100637716, COSV62122000; called by muse, mutect2, varscan2
- FKBP15 | c.1446G>A p.Q482= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs1263730880, COSV53039448; called by muse, mutect2, varscan2
- GSTA4 | c.57G>T p.V19= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs1296840446, COSV63373585; called by muse, mutect2, varscan2
- GUCY2C | c.2613C>A p.I871= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as COSV53786669, COSV53795582; called by muse, mutect2, varscan2
- IGKV2-28 | c.318G>A p.E106= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs1248736775; called by mutect2, varscan2
- JMJD1C | c.4227C>A p.S1409= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV100550856; called by muse, mutect2, varscan2
- KCTD16 | c.456C>T p.P152= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV72580691; called by muse, mutect2, varscan2
- KDR | c.3300C>T p.S1100= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as rs759365650, COSV55776060; called by muse, mutect2, varscan2
- LGALS9 | c.312G>T p.L104= | Silent (SNP) | VAF 43/201 reads (21%) | catalogued as COSV100119549; called by muse, varscan2
- LRRTM4 | c.1321T>C p.L441= | Silent (SNP) | VAF 48/141 reads (34%) | catalogued as rs1475792466, COSV69142254; called by muse, mutect2, varscan2
- MAN2B1 | c.180G>C p.P60= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV54418846, COSV54419597; called by muse, mutect2, varscan2
- MCCC2 | c.1068T>A p.V356= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV60156893; called by muse, mutect2, varscan2
- MIDEAS | c.2604G>A p.V868= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as rs1566582614, COSV54099056; called by muse, mutect2, varscan2
- MUC2 | c.651C>T p.S217= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs1414364486; called by muse, mutect2, varscan2
- OR1S2 | c.939C>T p.A313= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV56920760; called by muse, mutect2, varscan2
- PCDHA6 | c.591G>A p.K197= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV65350326, COSV65357851; called by muse, mutect2, varscan2
- PGLYRP3 | c.66C>T p.T22= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV51949964, COSV51951984; called by muse, mutect2, varscan2
- PROCA1 | c.51C>A p.T17= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV56388744; called by mutect2, varscan2
- PRPS2 | c.846A>G p.K282= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs1463412760, COSV66180291; called by muse, mutect2, varscan2
- RALGAPA2 | c.2271G>A p.Q757= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV52492048; called by muse, mutect2, varscan2
- RASSF6 | c.550A>C p.R184= (on ENST00000342081 / NM_201431.2; = p.R152= on NM_177532.5) | Silent (SNP) | VAF 76/245 reads (31%) | catalogued as COSV56721146; called by muse, mutect2
- RBMS3 | c.441C>G p.L147= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV56168745; called by muse, mutect2, varscan2
- SAFB | c.1494C>T p.D498= | Silent (SNP) | VAF 48/168 reads (29%) | catalogued as rs749049469, COSV52650004; called by muse, mutect2, varscan2
- SCN5A | c.1764T>C p.H588= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as rs775985491, COSV61140810; ClinVar: likely benign; called by muse, mutect2
- SLC22A16 | c.966G>A p.L322= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV57934674; called by muse, mutect2, varscan2
- SLC22A2 | c.93T>A p.A31= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100871063; called by muse, varscan2
- SLC9A7 | c.393C>T p.S131= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV60383657; called by muse, mutect2, varscan2
- SP140 | c.2373G>A p.A791= | Silent (SNP) | VAF 84/709 reads (12%) | catalogued as rs558534066, COSV100614111; called by muse, mutect2
- SREBF1 | c.2076C>T p.A692= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs770190474, COSV55419981; called by muse, mutect2, varscan2
- TAS2R40 | c.774C>T p.F258= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV68818675, COSV68818702; called by muse, varscan2
- TAT | c.501T>C p.P167= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV63533528; called by muse, mutect2
- TNFSF14 | c.33T>C p.F11= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV55591772; called by muse, mutect2, varscan2
- USH2A | c.7740A>T p.G2580= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as COSV56436317; called by muse, mutect2, varscan2
- VIPR1 | c.1195C>T p.L399= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV57298839; called by muse, mutect2, varscan2
- VTCN1 | c.330T>C p.V110= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as COSV60225501; called by muse, mutect2
- ZNF408 | c.1335C>T p.A445= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs762021380, COSV61239309; called by muse, mutect2
- AGAP7P | n.1599C>T | RNA (SNP) | VAF 33/193 reads (17%) | called by muse, mutect2, varscan2
- C3P1 | n.3100G>T | RNA (SNP) | VAF 57/202 reads (28%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-1975G>T | Intron (SNP) | VAF 24/114 reads (21%) | catalogued as COSV57933660; called by muse, mutect2, varscan2
- MBNL2 | c.805-643C>G | Intron (SNP) | VAF 30/121 reads (25%) | called by muse, mutect2, varscan2
- MIR450A2 | n.92A>G | RNA (SNP) | VAF 109/204 reads (53%) | called by muse, mutect2, varscan2
- SLC22A17 | n.1615C>T | RNA (SNP) | VAF 21/60 reads (35%) | catalogued as rs771629250, COSV52837489; called by muse, mutect2, varscan2
- ZNF536 | c.*2A>T | 3'UTR (SNP) | VAF 164/663 reads (25%) | catalogued as COSV100835983; called by muse, mutect2, varscan2
